CCDI case PBCJTI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2c51fea9-16b7-4ce1-ac56-8e850d10e78d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,084 days).

Biospecimens (3 samples)
- Sample 0DTLGB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTUHZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTUII: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
